FM case AD1688 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/6ddc144f-3378-4c09-920e-b40ff40e3833

Female, 54.0 years: diagnosis not reported by GDC; metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
